Surgical pathology report (de-identified scan), TCGA case TCGA-28-5204, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5204-01A (Primary Tumor).

[page 1 of 5]
TCGA - 28 - 5204

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional findings

DIAGNOSIS:

- A. BRAIN, LEFT TEMPORAL, BIOPSY:
- Glioblastoma multiforme, WHO grade IV
- B. BRAIN, LEFT TEMPORAL, BIOPSY:
- Glioblastoma multiforme, WHO grade IV
- C. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY:
- Glioblastoma multiforme, WHO grade IV
- D. BRAIN, LEFT TEMPORAL, BIOPSY, NCI #1:
- Glioblastoma multiforme, WHO grade IV
- 3% of tumor necrosis
- 95% of tumor cellularity
- E. BRAIN, LEFT TEMPORAL, BIOPSY, NCI #2:
- Glioblastoma multiforme, WHO grade IV
- 1% of tumor necrosis
- 95% of tumor cellularity
- F. BRAIN, LEFT TEMPORAL, BIOPSY, NCI #3:
- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity
- G. BRAIN, LEFT TEMPORAL, BIOPSY, NCI #4:
- Glioblastoma multiforme, WHO grade IV
- 20% of tumor necrosis
- 95% of tumor cellularity
- H. BRAIN, LEFT TEMPORAL, BIOPSY, NCI #5:
- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity
- I. BRAIN, LEFT TEMPORAL, BIOPSY, NCI #6:
- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity
- J. BRAIN, LEFT TEMPORAL, BIOPSY, NCI #7:
- Glioblastoma multiforme, WHO grade IV

[page 2 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

- 2% of tumor necrosis
- 95% of tumor cellularity

K, L. BRAIN, LEFT TEMPORAL, BIOPSY:

- Glioblastoma multiforme, WHO grade IV ✓

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. Hence, the 20% result in this case suggests the possibility of a relatively diminished response to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas.

Molecular subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of $\beta 1$ and $\beta 2$ in this tumor suggest the tumor aggressiveness intermediate between the $\beta 1 \downarrow$ (or normal)/ $\beta 2$ normal (or $\uparrow$) (the most favorable prognosis) and $\beta 1 \uparrow$ / $\beta 2 \downarrow$ (least favorable prognosis).

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme. Prognostic Associations of Activated Mitogen-Activated Protein Kinase and Akt Pathways in Glioblastoma.

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case may predict a relative resistance to radiation therapy.

IDC2a: Selected slides were reviewed in consultation with Dr. [REDACTED]

HISTORY: ✓

Brain tumor

MICROSCOPIC FINDINGS:

This infiltrating astrocytoma shows a small irregularly shaped angular and hyperchromatic nuclei associated with mitotic figures, endothelial proliferation and necrosis.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
MGMT	I1	20%
PTEN	I1	Retained (2+)
pMAPK	I1	70% of nuclei and 90% of tumor cytoplasm is positive

[page 3 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

Laminin beta-1 (8/411)	I1	Upregulated (3+)
Laminin beta-2 (9/421)	I1	Upregulated (3+)

GROSS:

A. BRAIN TUMOR LEFT TEMPORAL (FS)

Labeled with the patient's name, labeled "brain tumor left temporal (FS)" and received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin is a 0.9 x 0.6 x 0.5 cm soft brown-tan tissue. Entirely submitted.

Slide key:

A1. Remnant of FSA - 1

A2. 1

B. LEFT TEMPORAL, POSSIBLE CLINICAL TRIAL - STUDY

Labeled with the patient's name, labeled "left temporal, possible clinical trial study" and received in formalin is a 0.6 x 0.4 x 0.3 cm soft pink-tan tissue. Entirely submitted.

Slide key:

B1. 1

C. LEFT TEMPORAL PERMANENT

Labeled with the patient's name, labeled "left temporal permanent" and received in formalin is a 0.5 x 0.3 x 0.2 cm soft pink-tan tissue. Entirely submitted.

Slide key:

C1. 1

D. LEFT TEMPORAL NCI #1

Labeled with the patient's name, labeled "left temporal NCI #1" and received in formalin is a 0.8 x 0.5 x 0.4 cm soft pink-tan tissue. Entirely submitted.

Slide key:

D1. 1

E. LEFT TEMPORAL NCI #2

Labeled with the patient's name, labeled "left temporal NCI #2" and received in formalin is a 1.0 x 0.6 x 0.4 cm soft pink-tan tissue. Entirely submitted.

Slide key:

E1. 1

F. LEFT TEMPORAL NCI #3

Labeled with the patient's name, labeled "left temporal NCI #3" and received in formalin is a 0.8 x 0.6 x 0.4 cm pink-tan soft tissue. Entirely submitted.

Slide key:

F1. 1

G. LEFT TEMPORAL NCI #4

Labeled with the patient's name, labeled "left temporal NCI #4" and received in formalin is a 0.8 x 0.5 x 0.3 cm soft pink-tan tissue. Entirely submitted.

Slide key:

G1. 1

SURGICAL PATHOLOGY REPORT

[page 4 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

H. LEFT TEMPORAL NCI #5

Labeled with the patient's name, labeled "left temporal NCI #5" and received in formalin is a 1.2 x 1.0 x 0.3 cm soft pink-tan tissue. Entirely submitted.

Slide key:

H1. 1

I. LEFT TEMPORAL NCI #6

Labeled with the patient's name, labeled "left temporal NCI #6" and received in formalin is a 1.0 x 0.8 x 0.3 cm soft pink-tan tissue. Entirely submitted.

Slide key:

I1. 1

J. LEFT TEMPORAL NCI #7

Labeled with the patient's name, labeled "left temporal NCI #7" and received in formalin is a 0.7 x 0.4 x 0.4 cm soft pink-tan tissue. Entirely submitted.

Slide key:

J1. 1

K. LEFT TEMPORAL PERMANENT

Labeled with the patient's name, labeled "left temporal permanent" and received in formalin is a 3.5 x 2.5 x 0.5 cm aggregate of soft pink-tan tissue with focal hemorrhage. Entirely submitted.

Slide key:

K1. 3

K2. 4

L. LEFT TEMPORAL TUMOR

Labeled with the patient's name, labeled "left temporal tumor" and received in formalin is a 2.0 x 1.2 x 0.8 cm soft pink-tan mass. Upon sectioning, the cut surface is homogeneously yellow-tan with peripheral hemorrhage. Entirely submitted.

Slide key:

L1. 4

L2. 5

[REDACTED]

INTRAOPERATIVE CONSULTATION:
OPERATIVE CALL
OPERATIVE CONSULT (FROZEN AND TOUCH PREPS):

A. LEFT TEMPORAL FS + TP:

Glioblastoma.

[REDACTED]

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[REDACTED]

SURGICAL PATHOLOGY REPORT

[page 5 of 5]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****

ACCESSION #: [REDACTED]

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in BRAIN

Tissue Block: I1

RESULTS: POSITIVE for EGFR Amplification (See note below)

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed.

These studies showed amplification of the EGFR gene with a 11.8 ratio of EGFR signals to the centromere signals in 80% of the nuclei examined.

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $<40\%$ of the cells.

[REDACTED]

These FISH tests were developed and their performance characteristics determined by CSMC Cytogenetics Laboratory as required by the [REDACTED]. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[REDACTED]

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED]. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file 8d5cc868-2b44-4f4c-8857-3fa86915f603 (TCGA-28-5204.3E248730-BC16-4D33-A304-2E1093A3B45C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).